Somatic mutation profile of tumor specimen TCGA-67-4679-01B (aliquot TCGA-67-4679-01B-01D-1753-08) from TCGA case TCGA-67-4679, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; Age at diagnosis: 69.0 years (25,202 days).
Specimen TCGA-67-4679-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a88e0400-57c1-4a4b-a2bd-8aab4c106ccc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-67-4679-10A (Blood Derived Normal), aliquot TCGA-67-4679-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de00c77e-335d-443d-877e-7e39f17b55ee

The open-access MAF lists 307 somatic variants for this specimen: 233 protein-altering or splice-affecting, 67 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 190, Silent 67, Nonsense Mutation 24, Frame Shift Del 9, Splice Site 5, Frame Shift Ins 4, 5'UTR 2, RNA 2, 3'Flank 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 4/21 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ABCA8 | c.326A>T p.D109V | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV52193965; called by muse, mutect2, varscan2
- ABCG5 | c.234C>A p.S78R | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs748628439, COSV53209401, COSV53209655; called by muse, mutect2, varscan2
- ABL1 | c.1993G>T p.G665W | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as rs749748926, COSV100583603; called by muse, mutect2, varscan2
- ABL1 | c.1994G>T p.G665V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.206); catalogued as COSV100583610; called by muse, mutect2, varscan2
- ABR | c.1465C>G p.P489A (on ENST00000302538 / NM_021962.5; = p.P452A on NM_001092.5) | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV52141370, COSV52151796; called by muse, mutect2, varscan2
- ACTA1 | c.488A>T p.H163L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV64202859; called by muse, mutect2, varscan2
- ACTR3B | c.1142G>T p.G381V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55446158; called by muse, mutect2, varscan2
- ADAM19 | c.1504G>T p.D502Y | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57422597; called by muse, mutect2, varscan2
- ADAMTS16 | c.3092C>A p.T1031N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.139); catalogued as COSV56977629; called by muse, mutect2, varscan2
- ADGRA3 | c.3845G>T p.G1282V | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as COSV51560296; called by muse, mutect2, varscan2
- ADGRG3 | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV59650096; called by muse, mutect2, varscan2
- ADGRG4 | c.8018A>G p.H2673R | Missense Mutation (SNP) | VAF 81/171 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1405689053, COSV54949072; called by muse, mutect2, varscan2
- AGK | c.1253C>G p.T418R | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV62593791; called by muse, mutect2, varscan2
- AHCTF1 | c.4915G>T p.E1639* (on ENST00000366508; = p.E1613* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 23/114 reads (20%) | catalogued as COSV58245683; called by muse, mutect2, varscan2
- AKAP17A | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 72/211 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58308151; called by muse, mutect2, varscan2
- AKAP3 | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV57413629; called by muse, mutect2, varscan2
- AL645922.1 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as COSV54959182; called by muse, mutect2, varscan2
- ALLC | c.851G>A p.G284D | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52992851; called by muse, mutect2
- ALPK1 | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 37/107 reads (35%) | catalogued as COSV51581573; called by muse, mutect2, varscan2
- ANAPC4 | c.1375-1G>T p.X459_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | catalogued as COSV59542893; called by muse, mutect2
- ANTXR1 | c.427A>T p.S143C | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58008864; called by muse, mutect2, varscan2
- APPBP2 | c.1533T>G p.S511R | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV50025798; called by muse, mutect2, varscan2
- ARSI | c.745C>A p.L249M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.314); catalogued as COSV100155919; called by muse, mutect2, varscan2
- ASPM | c.3961G>T p.V1321F | Missense Mutation (SNP) | VAF 43/271 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.426); catalogued as rs758919365, COSV54124410, COSV54126482; called by muse, mutect2, varscan2
- ATG14 | c.1406G>A p.S469N | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.228); catalogued as COSV55955477; called by muse, mutect2, varscan2
- BCHE | c.718G>T p.G240* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | catalogued as COSV52253455; called by muse, mutect2, varscan2
- BCKDHB | c.929G>C p.W310S | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100243346, COSV100244012; called by muse, mutect2, varscan2
- BUD13 | c.162T>A p.D54E | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV52766915; called by muse, mutect2, varscan2
- C1orf189 | c.176T>A p.L59* | Nonsense Mutation (SNP) | VAF 99/308 reads (32%) | catalogued as COSV63890756; called by muse, mutect2, varscan2
- C9orf85 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 54/201 reads (27%) | catalogued as COSV58253391; called by muse, mutect2, varscan2
- CACNA1C | c.4909C>A p.Q1637K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.949); catalogued as COSV59696170; called by muse, mutect2, varscan2
- CACNA2D3 | c.475C>G p.H159D | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55512725, COSV55572983; called by muse, mutect2, varscan2
- CALCRL | c.1253G>T p.S418I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV66473394; called by muse, mutect2, varscan2
- CCDC141 | c.3587T>A p.L1196Q | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as COSV99836411; called by muse, mutect2, varscan2
- CCDC141 | c.2421G>C p.E807D | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV55383605; called by muse, mutect2, varscan2
- CCDC25 | c.310A>T p.M104L | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV62958306; called by muse, mutect2, varscan2
- CDH20 | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.315); catalogued as rs1467233461, COSV53004321; called by muse, mutect2, varscan2
- CDX2 | c.757C>G p.Q253E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.931); catalogued as COSV66829153; called by muse, mutect2
- CELA3A | c.689G>T p.W230L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV51581915; called by muse, mutect2, varscan2
- CEMIP2 | c.794G>T p.R265L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65485555; called by muse, mutect2, varscan2
- CETN1 | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.95); catalogued as COSV59120832; called by muse, mutect2
- CFAP65 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 32/97 reads (33%) | catalogued as COSV55389281, COSV55392286; called by muse, mutect2, varscan2
- CFH | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV62776207, COSV62777373; called by muse, mutect2, varscan2
- CMA1 | c.105C>A p.Y35* | Nonsense Mutation (SNP) | VAF 52/199 reads (26%) | catalogued as COSV51624876; called by muse, mutect2, varscan2
- CMYA5 | c.8555A>C p.Q2852P | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV71404059; called by muse, mutect2, varscan2
- CNDP2 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 33/115 reads (29%) | catalogued as COSV60838959, COSV60839519; called by muse, mutect2, varscan2
- CNTNAP2 | c.542G>C p.C181S | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62144210; called by muse, mutect2, varscan2
- CNTNAP5 | c.1790A>T p.Q597L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV70471880, COSV70484955; called by muse, mutect2, varscan2
- COL27A1 | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 145/279 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV61921391, COSV61929653; called by muse, mutect2, varscan2
- COL4A1 | c.2372G>T p.G791V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65421165; called by muse, mutect2, varscan2
- COL6A3 | c.2812G>T p.D938Y | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV55079460; called by muse, mutect2, varscan2
- COL6A6 | c.6054dup p.D2019Rfs*12 | Frame Shift Ins (INS) | VAF 15/45 reads (33%) | catalogued as rs745966034; called by mutect2, pindel, varscan2
- CPZ | c.935G>T p.G312V (on ENST00000360986 / NM_001014447.3; = p.G301V on NM_003652.3) | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748562079, COSV59921456; called by muse, mutect2, varscan2
- CSAD | c.547G>T p.A183S (on ENST00000444623 / NM_001244705.2; = p.A210S on NM_015989.5) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as COSV99914572; called by muse, mutect2, varscan2
- CSMD1 | c.3662C>A p.P1221Q (on ENST00000520002; = p.P1220Q on NM_033225.6) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs777083383, COSV59276597, COSV59310638; called by muse, mutect2, varscan2
- CTNNB1 | c.638G>T p.C213F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.035); catalogued as COSV62689214; called by muse, mutect2, varscan2
- CTNND2 | c.1417G>T p.G473C | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV58864290; called by muse, mutect2, varscan2
- CTSA | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.528); catalogued as rs779857539, COSV99509722; called by muse, mutect2, varscan2
- CTU2 | c.1195G>C p.A399P | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.52); catalogued as COSV56332978, COSV56341001; called by muse, mutect2, varscan2
- CUL9 | c.4366C>T p.R1456W | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1243912353, COSV52725092; called by muse, mutect2, varscan2
- DACH2 | c.1023C>A p.N341K | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1362283117, COSV64161618; called by muse, mutect2, varscan2
- DCK | c.406A>G p.I136V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV54377553; called by muse, mutect2, varscan2
- DENND2D | c.1115A>G p.N372S | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV62958477; called by muse, mutect2, varscan2
- DENND3 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.079); catalogued as COSV52800770; called by muse, mutect2, varscan2
- DHX16 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 24/109 reads (22%) | catalogued as rs781736063, COSV64562968; called by muse, mutect2, varscan2
- DNAH2 | c.328A>T p.T110S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV50013167; called by muse, mutect2, varscan2
- DNAH8 | c.2536T>A p.L846I | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV59423825; called by muse, mutect2, varscan2
- DSC1 | c.2386G>C p.G796R | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as COSV57141649; called by muse, mutect2, varscan2
- DSC3 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV64571636; called by muse, mutect2, varscan2
- EPC1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433910452, COSV53923041; called by muse, mutect2, varscan2
- EPN2 | c.1014G>T p.M338I | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV100127453; called by muse, mutect2, varscan2
- ERBB4 | c.2971G>A p.D991N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV61461518; called by muse, mutect2, varscan2
- F13A1 | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM040029, COSV53553155, COSV53554828; called by muse, mutect2, varscan2
- F5 | c.5835T>A p.Y1945* | Nonsense Mutation (SNP) | VAF 55/242 reads (23%) | catalogued as COSV63120278, COSV63122025; called by muse, mutect2, varscan2
- FAM135B | c.3137C>A p.S1046Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV52704222, COSV99422994; called by muse, mutect2, varscan2
- FAT3 | c.4945C>A p.P1649T | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53074450; called by muse, mutect2, varscan2
- FCHO1 | c.2426+2T>A p.X809_splice | Splice Site (SNP) | VAF 17/45 reads (38%) | catalogued as COSV53180633; called by muse, mutect2, varscan2
- FGA | c.868A>C p.S290R | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV57392747; called by muse, mutect2, varscan2
- FIP1L1 | c.619A>T p.T207S | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as COSV60993544; called by muse, mutect2, varscan2
- FMO1 | c.1469C>A p.T490N | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV61444578; called by muse, mutect2, varscan2
- GABRQ | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.855); catalogued as COSV64780789; called by muse, mutect2, varscan2
- GALNTL5 | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67179250; called by muse, mutect2, varscan2
- GALR1 | c.872T>A p.L291Q | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55315789; called by muse, mutect2, varscan2
- GAS1 | c.662A>T p.D221V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.684); catalogued as COSV100075718; called by muse, mutect2, varscan2
- GFPT2 | c.1934T>A p.L645H | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53806294; called by muse, mutect2, varscan2
- GJC1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs746106098, COSV57910469; called by muse, mutect2, varscan2
- GNAS | c.869T>C p.F290S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99669387; called by muse, mutect2, varscan2
- HAO2 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58037786, COSV58041028; called by muse, mutect2, varscan2
- HCN4 | c.2353G>T p.A785S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99983436; called by muse, mutect2
- HECW2 | c.2205G>T p.E735D | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.527); catalogued as rs775553074, COSV53648829; called by muse, mutect2, varscan2
- HNRNPH3 | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.351); catalogued as COSV56258498; called by muse, mutect2, varscan2
- HOXB1 | c.875C>A p.P292Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53318002, COSV99495377; called by muse, mutect2
- HOXB3 | c.1291C>A p.L431M | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57485750; called by muse, mutect2, varscan2
- IFITM5 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as rs768779464, COSV66888793; called by muse, mutect2, varscan2
- IPO13 | c.692A>C p.Q231P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100961075; called by muse, mutect2, varscan2
- IPO13 | c.693G>C p.Q231H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.643); catalogued as COSV100961076; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV101188149; called by muse, mutect2, varscan2
- JARID2 | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV59185059; called by muse, mutect2, varscan2
- KCNH2 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as COSV51126180; called by muse, mutect2, varscan2
- LAMA1 | c.440G>T p.S147I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as COSV67531877; called by muse, mutect2, varscan2
- LAMC3 | c.1682C>T p.T561I | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as rs199701268, COSV63088492; called by muse, mutect2, varscan2
- LAX1 | c.149T>A p.L50Q | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65848761; called by muse, mutect2, varscan2
- LCTL | c.1189T>A p.F397I | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV57178188; called by muse, mutect2, varscan2
- LEPR | c.2710G>A p.A904T | Missense Mutation (SNP) | VAF 65/206 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV62745411; called by muse, mutect2, varscan2
- LRFN2 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57823652; called by muse, mutect2, varscan2
- LRP1B | c.11998C>A p.H4000N | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.112); catalogued as COSV67185228; called by muse, mutect2, varscan2
- MAP2K3 | c.83C>A p.S28Y | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs1275616285, COSV57561722, COSV57565499; called by muse, mutect2, varscan2
- MAP3K4 | c.3626G>T p.G1209V | Missense Mutation (SNP) | VAF 59/101 reads (58%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV62330077; called by muse, mutect2, varscan2
- MAST4 | c.7267G>C p.G2423R (on ENST00000403625 / NM_001164664.2; = p.G2234R on NM_015183.3) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.37); catalogued as COSV55115402; called by muse, mutect2
- MB21D2 | c.1081C>T p.L361F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66661519; called by muse, mutect2, varscan2
- MMP21 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.059); catalogued as COSV64288595; called by muse, mutect2, varscan2
- MSGN1 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs749940776, COSV55262484; called by muse, mutect2, varscan2
- MTOR | c.4283C>T p.A1428V | Missense Mutation (SNP) | VAF 92/245 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV63868303; called by muse, mutect2, varscan2
- MUC16 | c.39133G>T p.G13045C | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.634); catalogued as rs747700066, COSV101201152, COSV67443820; called by muse, mutect2, varscan2
- MUC16 | c.13774G>A p.E4592K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); catalogued as rs1216619695, COSV67443825; called by muse, mutect2, varscan2
- MUC16 | c.1891A>T p.T631S | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.029); catalogued as COSV67443834; called by muse, mutect2, varscan2
- MUCL1 | c.176C>A p.T59N | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as COSV100445996; called by muse, mutect2, varscan2
- MYH1 | c.4255G>T p.E1419* | Nonsense Mutation (SNP) | VAF 38/97 reads (39%) | catalogued as COSV56843473; called by muse, mutect2, varscan2
- MYH2 | c.3184G>C p.E1062Q | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV55431310; called by muse, mutect2, varscan2
- MYO16 | c.1286A>T p.Q429L | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.654); catalogued as COSV51777088; called by muse, mutect2, varscan2
- MYO7A | c.1247C>G p.A416G | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as COSV68683352; called by muse, mutect2, varscan2
- NBEAL2 | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs758552948, COSV52754089; called by muse, mutect2
- NDUFB6 | c.240G>T p.W80C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100598254; called by muse, mutect2, varscan2
- NDUFB6 | c.239G>T p.W80L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100598258; called by muse, mutect2, varscan2
- NOTCH2 | c.1429G>C p.G477R | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.955); catalogued as COSV56681297; called by muse, varscan2
- NPHP3 | c.519G>C p.K173N | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58128495; called by muse, mutect2, varscan2
- NUDT12 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 45/117 reads (38%) | catalogued as COSV50090333; called by muse, mutect2, varscan2
- OPN4 | c.730T>C p.F244L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs372288717; called by muse, mutect2, varscan2
- OR10A2 | c.585G>A p.M195I | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.255); catalogued as COSV100224975; called by muse, mutect2, varscan2
- OR10K2 | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV59220312, COSV59220374; called by muse, mutect2
- OR10Q1 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs750937603, COSV57469675, COSV57469920; called by muse, mutect2, varscan2
- OR13A1 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV65571925; called by muse, mutect2
- OR1L3 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs1180306074, COSV100506214; called by muse, mutect2, varscan2
- OR2G6 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 58/108 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as rs757443337, COSV58573906, COSV58574355; called by muse, mutect2, varscan2
- OR2G6 | c.503T>G p.L168R | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.056); catalogued as COSV100598058; called by muse, mutect2, varscan2
- OR2Z1 | c.97G>C p.V33L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1568439403, COSV100136364; called by muse, mutect2, varscan2
- OR4C46 | c.640G>T p.V214F | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.595); catalogued as COSV60218294; called by muse, mutect2, varscan2
- OR51V1 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58314067; called by muse, mutect2, varscan2
- OR5F1 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV53545157, COSV53546649; called by muse, mutect2, varscan2
- OR5I1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.137); catalogued as rs777329573, COSV100041191, COSV56885436; called by muse, mutect2, varscan2
- OR6F1 | c.838G>C p.V280L | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as COSV57466739, COSV57467924; called by muse, mutect2, varscan2
- PADI1 | c.433G>T p.G145C | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64937737; called by muse, mutect2, varscan2
- PAX2 | c.106G>C p.V36L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100694992, COSV62290083; called by muse, mutect2, varscan2
- PCDH17 | c.1124G>T p.R375L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64971609, COSV64972310; called by muse, mutect2, varscan2
- PCDHGA8 | c.951G>T p.M317I | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.03); catalogued as COSV53896661, COSV53953422; called by muse, mutect2, varscan2
- PCDHGA8 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.12); catalogued as COSV53896684; called by muse, mutect2
- PDYN | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 38/114 reads (33%) | catalogued as COSV54100887, COSV99452811, COSV99453431; called by muse, mutect2, varscan2
- PDYN | c.354G>T p.K118N | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV99452816; called by muse, mutect2, varscan2
- PIGV | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99314815; called by muse, mutect2, varscan2
- PKD1 | c.6716C>T p.T2239M | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770643642, COSV51910490; called by muse, mutect2, varscan2
- PLEKHS1 | c.560G>A p.G187E (on ENST00000369310 / NM_182601.1; = p.G193E on NM_024889.5) | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.644); catalogued as rs1033066474, COSV63054015; called by muse, mutect2, varscan2
- PLIN4 | c.3872C>A p.A1291E (on ENST00000301286; = p.A1306E on NM_001367868.2) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56681225; called by muse, mutect2, varscan2
- POLR3A | c.3560A>T p.Y1187F | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV64930192; called by muse, mutect2, varscan2
- PSG6 | c.785A>T p.E262V | Missense Mutation (SNP) | VAF 109/304 reads (36%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.91); catalogued as COSV51829928; called by muse, mutect2, varscan2
- PSKH2 | c.974C>A p.A325E | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV52609103; called by muse, mutect2, varscan2
- PTPRK | c.3113G>T p.R1038L (on ENST00000368215 / NM_001291984.2; = p.R1039L on NM_002844.4) | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV63891051; called by muse, mutect2, varscan2
- PTPRT | c.1919C>A p.A640D | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.544); catalogued as COSV61959572; called by muse, mutect2, varscan2
- PXK | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 39/117 reads (33%) | catalogued as COSV57086427; called by muse, mutect2, varscan2
- PXMP4 | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54132637; called by muse, mutect2, varscan2
- RAB30 | c.307T>A p.W103R | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52625730; called by muse, mutect2, varscan2
- RAD18 | c.755C>G p.S252C | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53749073, COSV99368309; called by muse, mutect2
- RAD21 | c.971T>C p.L324P | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52056134; called by muse, mutect2, varscan2
- RD3 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1057304619, COSV100879199, COSV65363037; called by muse, mutect2, varscan2
- RGMA | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100224219; called by muse, mutect2, varscan2
- RHOU | c.262+2T>A p.X88_splice | Splice Site (SNP) | VAF 12/42 reads (29%) | catalogued as COSV64208252; called by muse, mutect2
- RIOK2 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51610825; called by muse, mutect2, varscan2
- ROBO2 | c.1097G>T p.S366I | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV59895984; called by muse, mutect2, varscan2
- RRP12 | c.3393C>T p.A1131= | Splice Region (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100213023; called by muse, mutect2, varscan2
- RYR2 | c.4603C>A p.P1535T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100769615, COSV63660633; called by muse, varscan2
- RYR2 | c.11032G>T p.E3678* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV100772243, COSV63660651; called by muse, mutect2, varscan2
- SDF4 | c.710A>G p.D237G | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV55417583; called by muse, mutect2, varscan2
- SERPINB8 | c.821A>T p.E274V | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54639019; called by muse, mutect2, varscan2
- SF3A1 | c.206C>G p.A69G | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53167158; called by muse, mutect2, varscan2
- SFSWAP | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV55519296; called by muse, mutect2, varscan2
- SIAH3 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV68551322; called by muse, mutect2, varscan2
- SIPA1L2 | c.2383G>T p.E795* | Nonsense Mutation (SNP) | VAF 41/193 reads (21%) | catalogued as COSV53383320; called by muse, mutect2, varscan2
- SLC44A5 | c.1134C>G p.F378L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1268958308, COSV63758297; called by muse, mutect2, varscan2
- SLC9C2 | c.877C>A p.P293T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV62943696; called by muse, mutect2, varscan2
- SNTG1 | c.1192-1G>T p.X398_splice | Splice Site (SNP) | VAF 40/103 reads (39%) | catalogued as COSV52423935; called by muse, mutect2, varscan2
- SOX8 | c.491A>G p.K164R | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV99559173; called by muse, mutect2, varscan2
- SPATA6 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 25/78 reads (32%) | catalogued as COSV64056387; called by muse, mutect2, varscan2
- SRRM3 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs545251939, COSV58385407; called by muse, mutect2
- STT3A | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs1288329292, COSV67064112; called by muse, mutect2, varscan2
- SULF1 | c.1831A>T p.T611S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52672933; called by muse, mutect2, varscan2
- SULT2A1 | c.567G>T p.Q189H | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV55764034; called by muse, mutect2, varscan2
- SUSD4 | c.771C>A p.H257Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100663571; called by muse, mutect2, varscan2
- SUSD4 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV59549748; called by muse, mutect2, varscan2
- SYNE3 | c.2912G>T p.G971V | Missense Mutation (SNP) | VAF 86/169 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62077797; called by muse, mutect2, varscan2
- TAS2R38 | c.170T>A p.L57Q | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71884952; called by muse, mutect2, varscan2
- TBCE | c.1090G>T p.A364S (on ENST00000366601; = p.A427S on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV64005092; called by muse, mutect2, varscan2
- TDRD3 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV52152981, COSV52160222; called by muse, mutect2
- TESMIN | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.022); catalogued as COSV54831315; called by muse, mutect2, varscan2
- THNSL2 | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV59081880; called by muse, mutect2, varscan2
- TMEM38B | c.726G>A p.W242* | Nonsense Mutation (SNP) | VAF 104/208 reads (50%) | catalogued as COSV65948895; called by muse, mutect2, varscan2
- TNPO2 | c.1232A>T p.K411M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV63507496; called by muse, mutect2, varscan2
- TNR | c.2054-2A>T p.X685_splice | Splice Site (SNP) | VAF 9/36 reads (25%) | catalogued as COSV54869625; called by muse, mutect2, varscan2
- TPH2 | c.1031T>G p.L344R | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61590397; called by muse, mutect2, varscan2
- TRHR | c.728C>A p.T243K | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100304591, COSV61232739; called by muse, mutect2, varscan2
- TRIM3 | c.626A>T p.E209V | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as COSV61983059; called by muse, mutect2, varscan2
- TRIM46 | c.902A>T p.H301L | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV55278170; called by muse, mutect2, varscan2
- TSSK1B | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.773); catalogued as COSV101180987; called by muse, mutect2, varscan2
- TUBB4A | c.193C>A p.L65M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV51152238; called by muse, mutect2, varscan2
- VANGL2 | c.1194G>T p.M398I | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV63603968; called by muse, mutect2, varscan2
- VWA2 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV53904825; called by muse, mutect2
- VWCE | c.453C>A p.C151* | Nonsense Mutation (SNP) | VAF 32/101 reads (32%) | catalogued as COSV57110814, COSV57110878; called by muse, mutect2, varscan2
- XIRP2 | c.4649C>A p.S1550* (on ENST00000628543; = p.S1725* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV54681902; called by muse, mutect2, varscan2
- ZC3H14 | c.176C>G p.T59R | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51766988; called by muse, mutect2, varscan2
- ZDBF2 | c.5795G>T p.R1932L | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.131); catalogued as COSV65621705, COSV65623112; called by muse, mutect2, varscan2
- ZER1 | c.1267A>T p.N423Y | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV52563940, COSV99402244; called by muse, mutect2, varscan2
- ZFHX4 | c.9161C>A p.T3054K | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50488582; called by muse, mutect2, varscan2
- ZFYVE28 | c.2470A>T p.T824S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.484); catalogued as COSV52107505; called by muse, mutect2, varscan2
- ZNF266 | c.428A>T p.D143V | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV63221440; called by muse, mutect2, varscan2
- ZNF493 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62749120; called by muse, mutect2, varscan2
- ZNF512B | c.2248G>T p.V750F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53865653, COSV99411592; called by muse, mutect2, varscan2
- ZNF79 | c.1334_1335del p.Y445* | Frame Shift Del (DEL) | VAF 84/204 reads (41%) | catalogued as rs1284089581; called by mutect2, pindel, varscan2
- ZNF831 | c.1279G>T p.V427L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64037205, COSV64039290; called by muse, mutect2, varscan2
- ZNF831 | c.1415C>A p.S472Y | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64037209; called by muse, mutect2, varscan2
- ZNF91 | c.2401G>T p.E801* | Nonsense Mutation (SNP) | VAF 29/90 reads (32%) | catalogued as COSV56080200; called by muse, mutect2, varscan2
- ZSCAN1 | c.467C>A p.A156E | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV56601596, COSV56601881; called by muse, mutect2, varscan2
- AGTR1 | c.397_398delinsA p.P133Kfs*2 | Frame Shift Del (DEL) | VAF 48/197 reads (24%) | called by pindel, varscan2*
- CAPZA2 | c.442dup p.I148Nfs*53 | Frame Shift Ins (INS) | VAF 19/57 reads (33%) | called by mutect2, varscan2
- FRG2 | c.56C>A p.T19N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by mutect2, varscan2
- GFRAL | c.233del p.F78Sfs*16 | Frame Shift Del (DEL) | VAF 34/121 reads (28%) | called by mutect2, pindel, varscan2
- HAPLN3 | c.1049del p.R350Pfs*41 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- INTS5 | c.1801del p.E601Nfs*21 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | called by mutect2, pindel, varscan2
- LRRC2 | c.178dup p.Q60Pfs*21 | Frame Shift Ins (INS) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- MAPK8 | c.661del p.H221Tfs*29 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | called by mutect2, pindel, varscan2
- NFIB | c.719del p.P240Qfs*14 | Frame Shift Del (DEL) | VAF 69/285 reads (24%) | called by mutect2, pindel, varscan2
- PLEKHG7 | c.125del p.P42Qfs*10 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- RASL12 | c.153dup p.N52Qfs*56 | Frame Shift Ins (INS) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- RBP3 | c.1729del p.R577Afs*124 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | called by mutect2, pindel, varscan2
- RYR3 | c.9812dup p.Y3271* (on ENST00000389232; = p.Y3272* on NM_001036.6) | Nonsense Mutation (INS) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- ACTL7B | c.852G>T p.P284= | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as COSV65926837, COSV65928188; called by muse, mutect2, varscan2
- ADAP2 | c.747G>T p.V249= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100437185; called by muse, mutect2, varscan2
- APAF1 | c.613C>A p.R205= (on ENST00000551964 / NM_181861.2; = p.R194= on NM_001160.3) | Silent (SNP) | VAF 44/129 reads (34%) | catalogued as COSV59661533, COSV59663721; called by muse, mutect2, varscan2
- APOBEC1 | c.540G>T p.L180= | Silent (SNP) | VAF 53/144 reads (37%) | catalogued as COSV99981035; called by muse, mutect2, varscan2
- ASMT | c.447C>A p.S149= | Silent (SNP) | VAF 53/188 reads (28%) | catalogued as COSV67109525; called by muse, mutect2, varscan2
- C8A | c.579C>T p.T193= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as rs773853618, COSV100776501, COSV63483053; called by muse, mutect2, varscan2
- CHRNB3 | c.480C>T p.F160= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV51493088; called by muse, mutect2, varscan2
- CRYBB1 | c.330C>A p.R110= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs766550440, COSV53232409, COSV53232466; called by muse, mutect2, varscan2
- CSF2RA | c.405C>T p.N135= | Silent (SNP) | VAF 95/245 reads (39%) | catalogued as COSV62623414; called by muse, mutect2, varscan2
- CYP26B1 | c.754C>A p.R252= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV50010691, COSV99134414; called by muse, mutect2, varscan2
- DDX60L | c.3565C>T p.L1189= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV52712222; called by mutect2, varscan2
- DIABLO | c.408A>T p.A136= (on ENST00000443649 / NM_001278303.1; = p.A209= on NM_019887.6) | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV57335681; called by muse, mutect2, varscan2
- DNAH10 | c.5262G>T p.V1754= (on ENST00000409039; = p.V1693= on NM_207437.3) | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV68987693; called by muse, mutect2, varscan2
- DPF3 | c.24C>A p.P8= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as COSV63498631; called by muse, mutect2, varscan2
- DSG4 | c.1446C>T p.T482= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV57388154; called by muse, mutect2, varscan2
- ESRRA | c.729C>A p.A243= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99134498; called by muse, mutect2
- FAM83D | c.1558T>C p.L520= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV54156472; called by muse, mutect2, varscan2
- FAT3 | c.3342C>T p.Y1114= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs542231640, COSV53074426; called by muse, mutect2, varscan2
- FFAR2 | c.252C>A p.L84= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV55831674, COSV55832284; called by muse, mutect2, varscan2
- FMN2 | c.2409C>A p.P803= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV60416522; called by muse, mutect2, varscan2
- FPR1 | c.525C>A p.A175= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV100493958; called by muse, mutect2, varscan2
- GAPT | c.372C>A p.I124= | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as COSV100576257; called by muse, mutect2, varscan2
- GPR179 | c.5085G>A p.E1695= (on ENST00000621958; = p.E1694= on NM_001004334.4) | Silent (SNP) | VAF 38/99 reads (38%) | called by muse, mutect2, varscan2
- H2AC12 | c.93G>A p.V31= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV63616666; called by muse, mutect2, varscan2
- HECTD1 | c.4332C>T p.S1444= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV67945015; called by muse, mutect2, varscan2
- HLX | c.72G>T p.S24= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs757694055, COSV65044298; called by muse, mutect2, varscan2
- KIF6 | c.1242T>G p.V414= | Silent (SNP) | VAF 37/184 reads (20%) | catalogued as COSV54666572; called by muse, mutect2, varscan2
- LARGE1 | c.294C>T p.H98= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV61657606; called by muse, mutect2, varscan2
- LONRF3 | c.729G>T p.A243= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV59149608; called by muse, mutect2, varscan2
- MED11 | c.162T>G p.A54= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV53411109; called by muse, mutect2
- MUSK | c.1119G>A p.L373= | Silent (SNP) | VAF 56/133 reads (42%) | catalogued as rs747717789, COSV51877862; called by muse, mutect2, varscan2
- MYLK | c.5427C>A p.P1809= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV60604531; called by muse, mutect2, varscan2
- NAPSA | c.912G>T p.G304= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV53796745; called by muse, mutect2, varscan2
- NEBL | c.1515T>G p.T505= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as rs546593564, COSV65801340; called by muse, mutect2, varscan2
- NECAB1 | c.576C>T p.S192= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs1563537029, COSV70236742; called by muse, mutect2, varscan2
- NHSL2 | c.738G>T p.S246= (on ENST00000510661; = p.S612= on NM_001013627.2) | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV65452342; called by muse, mutect2, varscan2
- NPHS1 | c.2724C>T p.N908= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs200269176, COSV62286302; called by muse, mutect2, varscan2
- NTRK3 | c.1842C>T p.I614= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1243756590, COSV62295428, COSV62318197; called by muse, mutect2, varscan2
- OR1L3 | c.273C>T p.T91= | Silent (SNP) | VAF 47/249 reads (19%) | catalogued as rs867330586, COSV100506215; called by muse, mutect2, varscan2
- OR8J3 | c.861C>A p.P287= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV56879318, COSV56880003; called by muse, mutect2, varscan2
- PAX4 | c.597C>A p.A199= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV58387249; called by muse, varscan2
- PBX4 | c.264G>C p.L88= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV52059806; called by muse, mutect2, varscan2
- PDLIM3 | c.570G>T p.T190= (on ENST00000284770 / NM_001257963.1; = p.T357= on NM_014476.6) | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV52977723, COSV52981552; called by muse, mutect2, varscan2
- PSD2 | c.1629C>T p.Y543= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as rs751218360, COSV51197070; called by muse, mutect2, varscan2
- REG1B | c.97C>A p.R33= | Silent (SNP) | VAF 74/215 reads (34%) | catalogued as rs185604160, COSV59304330, COSV59306460; called by muse, mutect2, varscan2
- RPH3A | c.1134G>A p.E378= (on ENST00000389385 / NM_001143854.2; = p.E374= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV66989932; called by muse, varscan2
- RPL3 | c.1017A>T p.G339= | Silent (SNP) | VAF 136/392 reads (35%) | catalogued as COSV53364652; called by muse, mutect2, varscan2
- SCN5A | c.2812C>T p.L938= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs1413327647, COSV61115438; called by muse, mutect2, varscan2
- SH3D21 | c.2028C>A p.V676= (on ENST00000453908 / NM_001162530.2; = p.V565= on NM_024676.5) | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99583965; called by muse, varscan2
- SIPA1L2 | c.4965C>A p.T1655= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV53383299; called by muse, mutect2, varscan2
- SLC12A1 | c.144C>T p.T48= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV57708135; called by muse, mutect2, varscan2
- SPATA31A3 | c.717C>T p.H239= | Silent (SNP) | VAF 38/108 reads (35%) | called by mutect2, varscan2
- SPINK2 | c.195G>A p.L65= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as COSV99954175; called by muse, mutect2, varscan2
- ST14 | c.1485G>T p.T495= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as COSV53831319; called by muse, mutect2, varscan2
- STAB1 | c.6705C>T p.A2235= | Silent (SNP) | VAF 5/102 reads (5%) | catalogued as rs1436150109, COSV58731977; called by muse, mutect2
- STAB2 | c.3774C>A p.I1258= | Silent (SNP) | VAF 42/97 reads (43%) | catalogued as COSV66333949; called by muse, mutect2, varscan2
- THSD1 | c.105A>T p.V35= | Silent (SNP) | VAF 53/168 reads (32%) | catalogued as COSV51626398; called by muse, mutect2, varscan2
- TRPC1 | c.1176A>T p.A392= (on ENST00000476941 / NM_001251845.2; = p.A358= on NM_003304.4) | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV56422761; called by muse, mutect2, varscan2
- VCAN | c.5028A>T p.I1676= | Silent (SNP) | VAF 46/114 reads (40%) | catalogued as COSV54096377; called by muse, mutect2, varscan2
- WDR7 | c.1800G>T p.G600= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV54347979; called by muse, mutect2, varscan2
- XIRP2 | c.6171C>T p.H2057= (on ENST00000628543; = p.H2232= on NM_152381.6) | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs370981896, COSV54681914; called by muse, mutect2, varscan2
- ZBED6CL | c.330T>C p.I110= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV100550392; called by muse, mutect2, varscan2
- ZBTB20 | c.414C>T p.S138= (on ENST00000474710 / NM_001164342.2; = p.S65= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV100613212, COSV61842859; called by muse, mutect2
- ZEB2 | c.12G>T p.P4= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV57951221; called by muse, mutect2, varscan2
- ZFHX4 | c.7659C>A p.G2553= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV50488423; called by muse, mutect2, varscan2
- ZNF229 | c.2103C>A p.T701= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV52159462; called by muse, mutect2, varscan2
- ZNF560 | c.1566G>A p.G522= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as COSV56865214; called by muse, mutect2, varscan2
- FOLH1B | n.818A>G | RNA (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- FRMPD2B | n.1022T>C | RNA (SNP) | VAF 29/95 reads (31%) | called by mutect2, varscan2
- KRT18P23 | chr22:44571463 G>A | 3'Flank (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- OR52A4P | chr11:5120985 G>T | 3'Flank (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- RBAK | c.-94G>T | 5'UTR (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100806601; called by muse, mutect2, varscan2
- STAU1 | c.-1del | 5'UTR (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- USH1C | c.1285-7674C>A | Intron (SNP) | VAF 10/18 reads (56%) | catalogued as COSV99139514; called by muse, mutect2, varscan2
